Surgical pathology report (de-identified scan), TCGA case TCGA-RW-A685, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Michigan University, specimen TCGA-RW-A685-01A (Primary Tumor).

PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:

PATIENT NBR:

PAGE #: 2
SEX: F

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE: SPHS

VERIFIED BY:

Right adrenal pheochromocytoma. Operative Procedure: Right adrenal laparoscopic adrenalectomy.

PROCEDURE: SPGD

VERIFIED BY:

1. "Right adrenal" Received in formalin in a small container, previously surgically incised without inking is a right adrenal gland (63.63 g). A 8.0 x 4.0 x 4.0 cm lobule of adipose and glandular tissue containing a 4.8 x 3.1 x up to 3.1 cm brown-tan, indurated mass appearing grossly free/encapsulated. The unoriented specimen shows on one aspect of it a 2.8 x up to 0.4 cm strip of grossly identifiable adrenal glandular parenchyma. Serial sectioning reveals a tan-gray, mottled adipose mass lesion which appears to arise from the adrenal gland itself.
1A-E. Sections sampling normal gland to mass and mass to overlying fibroadipose tissue and capsule.

PROCEDURE: SPDX

VERIFIED BY:

1. Right adrenal gland, adrenalectomy: Pheochromocytoma (4.8 cm). Margins free.

I, , the signing staff pathologist, have personally examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Source: NCI Genomic Data Commons file 3326c21e-bfc7-4eea-87ba-25ba812cfb16 (TCGA-RW-A685.7BDAE86C-AFC5-4191-927B-F1A1A50FA6A2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).